Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6464, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6464-01A (Primary Tumor).

Case ID	Subject ID	Formatted Path Report
		LARGE INTESTINE TISSUE CHECKLIST Specimen type: Abdominal perineal resection Specimen size: Not specified Tumor site: Rectosigmoid junction Tumor size: 7.5 x 0 x 7.2 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 0/12 positive for metastasis (Adjacent fatty tissue 0/12) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Date of Procurement

Source: NCI Genomic Data Commons file b4ac8179-a62c-46d4-9421-37e1dce1338f (TCGA-F5-6464.3ADC4714-AEE3-4E56-8A24-073D70632F60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).